Somatic mutation profile of tumor specimen TCGA-ZF-A9RE-01A (aliquot TCGA-ZF-A9RE-01A-11D-A38G-08) from TCGA case TCGA-ZF-A9RE, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 78.4 years (28,622 days).
Specimen TCGA-ZF-A9RE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07b8802b-d048-4dcc-869e-2791f665dc9f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZF-A9RE-10A (Blood Derived Normal), aliquot TCGA-ZF-A9RE-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/938a901a-da98-4f08-9c4b-819597cced99

The open-access MAF lists 59 somatic variants for this specimen: 47 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 11, Nonsense Mutation 3, Frame Shift Del 2, Frame Shift Ins 1, 3'UTR 1, In Frame Del 1, Nonstop Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.*174A>G | 3'UTR (SNP) | VAF 94/116 reads (81%) | catalogued as rs121913485, CM960657, COSV53390174; ClinVar: likely pathogenic / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3145G>C p.G1049R | Missense Mutation (SNP) | VAF 41/107 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen benign (0.096); catalogued as rs121913277, CM126700, COSV55874453, COSV55878564, COSV55919873; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 10/19 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACAD11 | c.982C>A p.L328I | Missense Mutation (SNP) | VAF 8/232 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.104); catalogued as COSV53895908; called by muse, mutect2
- ALLC | c.1151C>T p.S384L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs1367536265, COSV52996184, COSV99377665; called by muse, mutect2, varscan2
- ARAP2 | c.1816G>A p.V606M | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as COSV58293290; called by muse, mutect2, varscan2
- ARHGAP20 | c.3191T>A p.I1064K | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0.01); catalogued as COSV52820189; called by muse, mutect2, varscan2
- ATG4C | c.55G>T p.A19S | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs760890086, COSV58608887; called by muse, mutect2, varscan2
- BCAS3 | c.1752C>G p.I584M (on ENST00000390652 / NM_001353144.2; = p.I569M on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV66783130; called by muse, mutect2
- BRINP2 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs1419220723, COSV64175373; called by muse, mutect2, varscan2
- CALD1 | c.1994C>T p.S665L (on ENST00000361675 / NM_033138.4; = p.S410L on NM_004342.7) | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.159); catalogued as rs1372249532, COSV62654897; called by muse, mutect2, varscan2
- CAMSAP1 | c.3730C>G p.P1244A | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as COSV56729089; called by muse, mutect2, varscan2
- CCT8L2 | c.1228C>G p.P410A | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.351); catalogued as COSV63463946, COSV63463964; called by muse, mutect2, varscan2
- CHPT1 | c.454C>G p.R152G | Missense Mutation (SNP) | VAF 4/90 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.028); catalogued as COSV99977873; called by muse, mutect2
- CNTNAP5 | c.1312G>T p.E438* | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | catalogued as COSV101442982; called by muse, mutect2, varscan2
- DICER1 | c.4595A>G p.E1532G | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58629241; called by muse, mutect2, varscan2
- DMRT1 | c.444A>C p.K148N | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66524913; called by muse, mutect2, varscan2
- F8 | c.4345G>T p.E1449* | Nonsense Mutation (SNP) | VAF 65/192 reads (34%) | catalogued as CM094293, COSV64278947; called by muse, mutect2, varscan2
- GBP2 | c.524C>A p.A175E | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as COSV65070482, COSV65070604; called by muse, mutect2
- GBP4 | c.1163A>C p.K388T | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV63256247; called by muse, mutect2
- GLTP | c.630G>C p.*210Yext*28 | Nonstop Mutation (SNP) | VAF 21/248 reads (8%) | catalogued as COSV100570416; called by muse, mutect2
- GPBP1L1 | c.178C>G p.R60G | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV51967094, COSV51973682; called by muse, mutect2, varscan2
- GRAMD1A | c.1346G>A p.R449H | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs200063858; called by muse, mutect2, varscan2
- KCNQ3 | c.1370C>A p.P457H | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66483260; called by muse, mutect2, varscan2
- KCNQ5 | c.1409G>A p.R470Q | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs766811320, COSV59685070; called by muse, mutect2, varscan2
- MAGEB16 | c.566C>T p.T189I | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs754132440, COSV101303329, COSV67874722; called by muse, mutect2, varscan2
- MYH11 | c.2315C>G p.T772S | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV55572092; called by muse, mutect2
- NEXMIF | c.2648G>A p.S883N | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV50159556; called by muse, mutect2, varscan2
- NWD1 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs201116385; called by muse, mutect2, varscan2
- PCDH19 | c.1574A>G p.Q525R | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV55272558; called by muse, mutect2, varscan2
- PCNX1 | c.1554T>A p.S518R | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV53103127; called by muse, mutect2, varscan2
- PNISR | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as rs1451581179, COSV65079096, COSV99053988; called by muse, mutect2, varscan2
- PPP1R36 | c.1249C>T p.H417Y | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV53903784, COSV53904132; called by muse, mutect2
- RFPL2 | c.173T>A p.L58H | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); catalogued as COSV50719569; called by muse, mutect2
- RTL9 | c.1805C>A p.S602Y | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV71826533; called by muse, mutect2, varscan2
- SLC26A7 | c.815_829del p.A272_N277delinsD | In Frame Del (DEL) | VAF 12/54 reads (22%) | catalogued as COSV52605694; called by mutect2, pindel, varscan2
- SOCS3 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58271576; called by muse, mutect2
- STAG2 | c.2314T>C p.C772R | Missense Mutation (SNP) | VAF 91/225 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762388218, COSV54350278; called by muse, mutect2, varscan2
- STXBP5 | c.400A>G p.I134V | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs756936155, COSV51658929; called by muse, mutect2, varscan2
- SVEP1 | c.6898A>C p.S2300R | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as COSV52838682, COSV52844705; called by muse, mutect2
- VARS2 | c.2261G>A p.R754H | Missense Mutation (SNP) | VAF 65/111 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1244836047, COSV58913691, COSV58914684; called by muse, mutect2, varscan2
- VWF | c.955G>T p.E319* | Nonsense Mutation (SNP) | VAF 7/67 reads (10%) | catalogued as COSV54628084, COSV99780462; called by muse, mutect2, varscan2
- ZNF25 | c.458A>T p.K153I | Missense Mutation (SNP) | VAF 77/149 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as COSV56924360; called by muse, mutect2, varscan2
- ZNF471 | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as rs142290015; called by muse, mutect2, varscan2
- CYP4F8 | c.1112_1115+1del | Frame Shift Del (DEL) | VAF 13/55 reads (24%) | called by mutect2, pindel, varscan2
- KDM6A | c.443+2dup p.X148_splice | Splice Site (INS) | VAF 18/68 reads (26%) | called by mutect2, pindel, varscan2
- MYOF | c.3498_3499del p.I1166Mfs*10 | Frame Shift Del (DEL) | VAF 42/76 reads (55%) | called by mutect2, pindel, varscan2
- THRAP3 | c.2459dup p.P822Sfs*3 | Frame Shift Ins (INS) | VAF 18/49 reads (37%) | called by mutect2, pindel, varscan2
- ABCA12 | c.6204C>T p.G2068= (on ENST00000272895 / NM_173076.3; = p.G1750= on NM_015657.3) | Silent (SNP) | VAF 42/118 reads (36%) | catalogued as rs777822338, COSV55959406; called by muse, mutect2, varscan2
- ARHGEF26 | c.1995T>C p.Y665= | Silent (SNP) | VAF 41/112 reads (37%) | catalogued as COSV62852554; called by muse, mutect2, varscan2
- BPTF | c.2271C>T p.N757= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as rs779058124; called by mutect2, varscan2
- F9 | c.978G>T p.V326= | Silent (SNP) | VAF 20/169 reads (12%) | catalogued as COSV54382700; called by muse, mutect2, varscan2
- GTPBP1 | c.969G>A p.K323= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV53288199; called by muse, mutect2, varscan2
- IFT172 | c.705C>T p.S235= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as rs1200322917, COSV99563543; called by muse, mutect2
- LCP2 | c.318G>A p.S106= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs371208606; called by muse, mutect2, varscan2
- MMP17 | c.639C>T p.P213= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as rs138755759, COSV100861989; called by muse, mutect2, varscan2
- NALCN | c.1245C>T p.Y415= | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as rs1426944195, COSV51968781; called by muse, mutect2, varscan2
- PCDHGA2 | c.2226C>T p.G742= | Silent (SNP) | VAF 60/138 reads (43%) | catalogued as rs1278697431, COSV53985011; called by muse, mutect2, varscan2
- PLXNB3 | c.3120A>G p.L1040= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs1557062773, COSV62802944; called by muse, mutect2, varscan2
